TCGA case TCGA-HZ-A4BK — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/514d12b0-6f60-406e-bde9-a090e918ebff

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 72.6 years (26,503 days); Year of diagnosis: 2012; Method of diagnosis: Cytology; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 657 days (1.8 years); Sites of involvement: Pancreas Head; Tumor grade category: Four Tier.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 4; Tumor largest dimension diameter: 4.7 cm.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 130 days; Days to treatment end: 532 days (1.5 years); Treatment dose: 4,500 cGy; Treatment outcome: Progressive Disease; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 136 days; Days to treatment end: 228 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Whipple.
2. Clear cell carcinoma: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Kidney, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 64.0 years (23,366 days); Days to diagnosis: -3,137 days (-8.6 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -3,137 days (-8.6 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 657 days (1.8 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 46.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HZ-A4BK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 70 mg.
  Slide TCGA-HZ-A4BK-01A-01-TS1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 45; Percent normal cells: 20; Percent necrosis: 3; Percent stromal cells: 47; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-HZ-A4BK-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HZ-A4BK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma-Other Subtype; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymph nodes examined: Yes; Alcohol history documented: No; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Drug treatment: Pharmaceutical therapy drug name: Chemo, NOS; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Kidney; Other malignancy histological type: Kidney Clear Cell Renal Carcinoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 657 days; disease-specific survival: no event (censored), 657 days; progression-free interval: no event (censored), 657 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HZ-A4BK-01A-11D-A26H-01): tumor purity 0.19, ploidy 3.32, whole-genome doublings 1.
